Somatic mutation profile of tumor specimen C3N-00377-02 (aliquot CPT0021650009) from CPTAC case C3N-00377, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.7 years (23,630 days).
Specimen C3N-00377-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d194c0f2-978a-40dd-ac47-98f0ed317440.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00377-71 (Blood Derived Normal), aliquot CPT0021710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75924c24-5f03-4257-a35c-ace486b7a2a9

The open-access MAF lists 679 somatic variants for this specimen: 444 protein-altering or splice-affecting, 142 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 302, Silent 142, Frame Shift Del 85, Intron 47, Frame Shift Ins 29, Nonsense Mutation 20, 3'UTR 19, RNA 10, 5'UTR 9, 3'Flank 5, Splice Region 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 134/317 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 59/175 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>G p.N549K | Missense Mutation (SNP) | VAF 159/380 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 156/439 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPGR | c.2520+1412dup | Intron (INS) | VAF 156/484 reads (32%) | catalogued as rs886041376; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA7 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs145667385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG8 | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.905); catalogued as rs1358575116, COSV55396265; called by muse, mutect2
- ABHD4 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs142817719; called by muse, mutect2, varscan2
- ACCSL | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs764834531, COSV66580511, COSV66582266; called by muse, mutect2, varscan2
- ACRBP | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 46/97 reads (47%) | catalogued as rs764217842, COSV99976002; called by muse, mutect2, varscan2
- ADAD2 | c.1204C>T p.R402C (on ENST00000315906 / NM_001145400.2; = p.R484C on NM_139174.4) | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs199788542, COSV51895071; called by muse, mutect2, varscan2
- ADAMTS14 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV64603600; called by muse, mutect2, varscan2
- ADPGK | c.1232C>T p.T411I | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as rs371006530; called by muse, mutect2, varscan2
- AMPD2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as rs1308492888; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as rs546686089; called by mutect2, varscan2
- ARFGEF3 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52470104; called by muse, mutect2, varscan2
- ARHGAP30 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100920276; called by muse, mutect2, varscan2
- ARHGEF18 | c.1556C>T p.P519L (on ENST00000359920 / NM_001130955.2; = p.P415L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966571777, COSV60467104; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as rs1295666772; called by mutect2, varscan2
- ARSD | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.229); catalogued as rs746849848; called by muse, mutect2, varscan2
- ATG13 | c.1054G>A p.V352I (on ENST00000359513 / NM_001346321.1; = p.V315I on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs201400137; called by muse, mutect2, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 31/133 reads (23%) | catalogued as COSV52486004; called by mutect2, pindel, varscan2
- BAG6 | c.1169del p.P390Qfs*61 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs745882580; called by mutect2, varscan2
- BEND5 | c.175dup p.R59Pfs*22 | Frame Shift Ins (INS) | VAF 42/126 reads (33%) | catalogued as rs1361801455; called by mutect2, pindel, varscan2
- BTBD10 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 62/214 reads (29%) | catalogued as rs752423002; called by muse, mutect2, varscan2
- C1orf141 | c.363dup p.P122Tfs*2 | Frame Shift Ins (INS) | VAF 9/17 reads (53%) | catalogued as rs145606616; called by mutect2, varscan2
- CASP5 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs867070721, COSV52826675; called by muse, mutect2, varscan2
- CCDC85A | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs753705942; called by muse, mutect2, varscan2
- CCDC85C | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs765861961; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 52/132 reads (39%) | catalogued as rs753353408; called by mutect2, varscan2
- CEP192 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs752095796, COSV58061853; called by muse, mutect2, varscan2
- CFAP58 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | catalogued as rs761844995; called by mutect2, varscan2
- CHD3 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs751264217; called by muse, mutect2, varscan2
- CHRM2 | c.648G>T p.R216S | Missense Mutation (SNP) | VAF 165/444 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57768592; called by muse, mutect2, varscan2
- CLK3 | c.785G>A p.R262H (on ENST00000395066 / NM_001130028.1; = p.R114H on NM_003992.4) | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs773020998, COSV61411858; called by muse, mutect2, varscan2
- COL2A1 | c.509dup p.G171Wfs*18 | Frame Shift Ins (INS) | VAF 92/263 reads (35%) | catalogued as COSV61530596; called by mutect2, pindel, varscan2
- COL6A3 | c.7415A>T p.K2472M | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV55090284; called by muse, mutect2, varscan2
- CRACDL | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1293975643, COSV67408702; called by muse, mutect2, varscan2
- CRACR2B | c.1039C>T p.R347W (on ENST00000525077 / NM_001286606.2; = p.T291M on NM_173584.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374170179; called by muse, mutect2, varscan2
- CRYBG3 | c.6462G>T p.E2154D | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs1387471206; called by muse, mutect2, varscan2
- CSMD3 | c.8055G>T p.K2685N (on ENST00000297405 / NM_001363185.1; = p.K2581N on NM_052900.3) | Missense Mutation (SNP) | VAF 104/291 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV52183093; called by muse, mutect2, varscan2
- CYB5R3 | c.636C>T p.T212= | Splice Region (SNP) | VAF 71/228 reads (31%) | catalogued as rs745689124, COSV61545315; called by muse, mutect2, varscan2
- DCHS1 | c.9154C>T p.R3052C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs530903190; called by muse, mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs757771764; called by mutect2, varscan2
- DIP2B | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771933340, COSV56585872; called by muse, mutect2, varscan2
- DMTF1 | c.1244del p.N415Tfs*28 | Frame Shift Del (DEL) | VAF 114/278 reads (41%) | catalogued as rs1348399160; called by mutect2, varscan2
- DMXL2 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs375978467; called by muse, mutect2, varscan2
- DNAAF1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371065429, COSV57577747, COSV99043957; called by muse, mutect2
- DNAJC3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs777878071, COSV100953398; called by muse, mutect2, varscan2
- DOCK4 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs780012495; called by muse, mutect2, varscan2
- DPPA2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs750894184, COSV101524806; called by muse, mutect2, varscan2
- DSC2 | c.2117T>C p.L706S | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772498376; called by muse, mutect2, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 39/131 reads (30%) | catalogued as rs1381179969; called by mutect2, varscan2
- DVL1 | c.1295G>A p.R432H (on ENST00000378888 / NM_001330311.2; = p.R407H on NM_004421.3) | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1384067368; called by muse, mutect2, varscan2
- ECM2 | c.65dup p.N22Kfs*2 | Frame Shift Ins (INS) | VAF 54/170 reads (32%) | catalogued as rs765348782; called by mutect2, pindel, varscan2
- ECT2L | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100871819; called by muse, mutect2, varscan2
- EIF4G3 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.398); catalogued as rs749614914; called by muse, mutect2, varscan2
- ELK3 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 153/407 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs761945544, COSV57388319; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- EML6 | c.4070del p.K1357Rfs*9 | Frame Shift Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs746682537; called by mutect2, varscan2
- ENKD1 | c.640del p.R214Gfs*14 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | catalogued as rs772512087; called by mutect2, pindel, varscan2
- ENTPD2 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs563908073, COSV57075830; called by muse, mutect2, varscan2
- ENTPD4 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs887446660; called by muse, mutect2, varscan2
- EPHA8 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751977374, COSV51289090; called by muse, mutect2, varscan2
- ERN2 | c.757_758del p.L253Afs*41 | Frame Shift Del (DEL) | VAF 80/327 reads (24%) | catalogued as rs771445771; called by pindel, varscan2
- FCHO1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs1443993812, COSV99405813; called by muse, mutect2, varscan2
- FGFR2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs113014479, COSV60649219; called by muse, mutect2, varscan2
- FNDC1 | c.3088del p.Q1030Sfs*6 | Frame Shift Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs754793587, COSV51938407; called by mutect2, pindel, varscan2
- FOXI2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs1220722036; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FZD6 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as rs767273753, CM120932; called by muse, mutect2, varscan2
- GABRP | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 144/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746391946; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA2 | c.2270C>A p.A757D | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV100360556; called by muse, mutect2, varscan2
- GRHPR | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1209918450; called by muse, mutect2, varscan2
- GRIA1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377273074; called by muse, mutect2, varscan2
- GTDC1 | c.901T>C p.F301L | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV54003716; called by muse, mutect2, varscan2
- H1-7 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 121/355 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as rs867635739, COSV58602836; called by muse, mutect2, varscan2
- HEATR5B | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs775104970, COSV51853366; called by muse, mutect2
- HELZ2 | c.6616dup p.R2206Pfs*42 (on ENST00000467148 / NM_001037335.2; = p.R1637Pfs*42 on NM_033405.3) | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | catalogued as rs745497383; called by mutect2, varscan2
- HR | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs560434995, COSV100455826; called by muse, mutect2, varscan2
- HR | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 142/423 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs544001441; called by muse, mutect2, varscan2
- HRH1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs200066638, COSV67955397, COSV67955826; called by muse, mutect2, varscan2
- HYPK | c.39_40del p.E14Dfs*15 | Frame Shift Del (DEL) | VAF 86/272 reads (32%) | catalogued as rs774320585; called by mutect2, pindel, varscan2
- ICE1 | c.6068C>T p.P2023L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99665799; called by muse, mutect2
- IGFBPL1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs1040030782; called by muse, mutect2, varscan2
- IGHG2 | c.371del p.P124Qfs*8 | Frame Shift Del (DEL) | VAF 75/392 reads (19%) | catalogued as rs1567185953; called by mutect2, pindel, varscan2
- IGHV2-5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 160/424 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as rs369263980; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 62/114 reads (54%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSR | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 157/410 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM140404; called by muse, mutect2, varscan2
- ITGBL1 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.993); catalogued as COSV66006818; called by muse, varscan2
- ITGBL1 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs761611322, COSV66009620; called by muse, mutect2, varscan2
- KCNS1 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60260502; called by muse, mutect2, varscan2
- KIF4B | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs758942033; called by muse, mutect2, varscan2
- KIF5C | c.1590G>C p.Q530H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV68481446; called by muse, mutect2
- LAMA3 | c.7817C>T p.T2606M (on ENST00000313654 / NM_198129.4; = p.T997M on NM_000227.6) | Missense Mutation (SNP) | VAF 168/481 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781307057; called by muse, mutect2, varscan2
- LARS2 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs144922552; called by muse, mutect2, varscan2
- LMX1B | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 145/420 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs767072869, COSV62742039; called by muse, mutect2, varscan2
- LRP2 | c.3046del p.D1016Tfs*170 | Frame Shift Del (DEL) | VAF 131/351 reads (37%) | catalogued as COSV55564032; called by mutect2, pindel, varscan2
- LRPAP1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1175921366, COSV56347360; called by muse, mutect2, varscan2
- LRRC4B | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs963312479; called by muse, mutect2, varscan2
- LRRN4CL | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748837919, COSV54016871; called by muse, mutect2, varscan2
- LYSMD1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184513568; called by muse, mutect2, varscan2
- LZTS1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs372940217; called by muse, mutect2, varscan2
- MED12L | c.417dup p.E140Rfs*9 | Frame Shift Ins (INS) | VAF 42/124 reads (34%) | catalogued as rs879130570; called by mutect2, pindel, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 56/175 reads (32%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- MEGF8 | c.6325C>T p.R2109W (on ENST00000251268 / NM_001271938.2; = p.R2042W on NM_001410.3) | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1371529001; called by muse, mutect2, varscan2
- MLNR | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs1362445968; called by muse, mutect2, varscan2
- MPP3 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs752209290, COSV68199421; called by muse, mutect2, varscan2
- MTSS2 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1260168371; called by muse, mutect2, varscan2
- MUC4 | c.5375G>A p.R1792H | Missense Mutation (SNP) | VAF 129/327 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.517); catalogued as rs774527434; called by muse, mutect2, varscan2
- MYF6 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs770081936, COSV57353849; called by muse, mutect2, varscan2
- MYO1F | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 140/393 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778366731; called by muse, mutect2, varscan2
- NAGS | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs766125863; called by muse, mutect2, varscan2
- NBPF9 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 95/645 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs587768291; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCKIPSD | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs143436723; called by muse, mutect2, varscan2
- NID2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV53492942; called by muse, mutect2, varscan2
- NLRP5 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs367708838; called by muse, mutect2, varscan2
- NOG | c.252del p.E85Rfs*39 | Frame Shift Del (DEL) | VAF 52/146 reads (36%) | catalogued as rs749247710, COSV100240560; called by mutect2, varscan2
- NPAS3 | c.2210C>T p.A737V (on ENST00000356141 / NM_001164749.2; = p.A705V on NM_022123.3) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1211665781; called by muse, mutect2, varscan2
- NPY2R | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs755838016, COSV61527886, COSV61528318; called by muse, mutect2, varscan2
- NRG2 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs1319225282; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | catalogued as rs776154715; called by mutect2, varscan2
- OPHN1 | c.1801G>A p.V601I | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100830446; called by muse, mutect2, varscan2
- OR11G2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV62133196; called by muse, mutect2, varscan2
- OR4K2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 38/192 reads (20%) | catalogued as COSV100064689; called by muse, mutect2, varscan2
- P2RY8 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1477249111; called by muse, mutect2
- PACS2 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV57650079; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.175G>A p.A59T (on ENST00000374531 / NM_001037293.2; = p.A57T on NM_007203.5) | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs765301198, COSV57128790; called by muse, mutect2, varscan2
- PCDHA6 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 134/360 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65349232; called by muse, mutect2, varscan2
- PCDHB14 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); catalogued as COSV104381997; called by muse, mutect2, varscan2
- PDE5A | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs964954525, COSV99308869; called by muse, mutect2, varscan2
- PID1 | c.595G>A p.A199T (on ENST00000354069 / NM_001330156.1; = p.A197T on NM_017933.5) | Missense Mutation (SNP) | VAF 171/423 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761090784, COSV62476489; called by muse, mutect2, varscan2
- PLK1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs756741138, COSV55622415; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs953293505; called by mutect2, pindel
- PMFBP1 | c.1937G>A p.R646Q (on ENST00000537465; = p.R641Q on NM_031293.3) | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs776325314, COSV52822054, COSV52825354; called by muse, mutect2, varscan2
- PNPLA2 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs766417535; called by muse, mutect2, varscan2
- POM121 | c.3305C>T p.S1102L (on ENST00000434423; = p.S837L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.541); catalogued as rs782034707; called by muse, mutect2, varscan2
- POU6F2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 84/271 reads (31%) | catalogued as COSV101302580; called by muse, mutect2, varscan2
- PPDPF | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV64547542; called by muse, mutect2, varscan2
- PPP4R3B | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55401358; called by muse, mutect2, varscan2
- PRDM9 | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 172/497 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.532); catalogued as rs745800729, COSV57004092; called by muse, mutect2, varscan2
- PREX1 | c.1496G>A p.G499D | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV64253299; called by muse, mutect2, varscan2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs763575972; called by mutect2, varscan2
- PTEN | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204863, CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- PTPRS | c.1865del p.P622Lfs*16 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs755108907; called by mutect2, pindel
- PTPRZ1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as rs1469276203, COSV66432630; called by muse, mutect2, varscan2
- PXDN | c.3391C>T p.P1131S | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV99415404; called by muse, mutect2
- RAB31 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs777716997; called by muse, mutect2, varscan2
- RAD54B | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746313459, COSV60251056; called by muse, mutect2, varscan2
- RARRES2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs199705366; called by muse, mutect2, varscan2
- RIMS1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 127/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1044390019, COSV53488608; called by muse, mutect2, varscan2
- ROCK2 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1421981372, COSV99837870; called by muse, mutect2, varscan2
- RPL19 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV56636332; called by muse, mutect2, varscan2
- RXRA | c.332del p.L111Rfs*57 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as COSV62683760; called by mutect2, pindel, varscan2
- SCAF1 | c.2590G>A p.V864I | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.407); catalogued as rs761471149, COSV62182852; called by muse, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 47/187 reads (25%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs751191303; called by mutect2, varscan2
- SH3KBP1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1432635413, COSV65645947; called by muse, mutect2, varscan2
- SIGLEC12 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs779174939; called by muse, mutect2, varscan2
- SLC13A3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs373953053; called by muse, mutect2, varscan2
- SLC35E2B | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 132/452 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1478398339; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 36/101 reads (36%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC43A2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs748312090, COSV56768978; called by muse, mutect2, varscan2
- SLC47A1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV54499005; called by muse, mutect2
- SLC49A3 | c.1243del p.E415Rfs*12 (on ENST00000404286 / NM_001294341.2; = p.E414Rfs*12 on NM_032219.4) | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs762857248; called by mutect2, pindel, varscan2
- SLC6A17 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs1164934275, COSV58992846; called by muse, mutect2, varscan2
- SLFN12 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59225188; called by muse, mutect2, varscan2
- SLFN13 | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs771148981, COSV53194499; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as rs745834619; called by mutect2, varscan2
- SNED1 | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs748990545; called by muse, mutect2, varscan2
- SNX18 | c.249del p.G85Afs*141 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs1298216865; called by mutect2, pindel, varscan2
- SP140 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV59455901; called by muse, mutect2, varscan2
- SPTBN1 | c.6320C>T p.T2107M | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs766647948, COSV61690257; called by muse, mutect2, varscan2
- SPTBN4 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV100150578; called by muse, mutect2, varscan2
- SRP72 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756816276, COSV61377903; called by muse, mutect2, varscan2
- ST7 | c.1394C>T p.T465M (on ENST00000265437 / NM_021908.3; = p.T442M on NM_018412.4) | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1214508438; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STEAP3 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV100713424; called by muse, mutect2, varscan2
- STK11IP | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs187483004, COSV55253409; called by muse, mutect2, varscan2
- SWT1 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 100/176 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62254011; called by muse, mutect2, varscan2
- TAF1L | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 175/468 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1251848812; called by muse, mutect2, varscan2
- TANC1 | c.4501C>T p.P1501S | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1431506091; called by muse, mutect2, varscan2
- TBC1D12 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs757453586, COSV56558718; called by muse, mutect2, varscan2
- TCF20 | c.4549G>A p.D1517N | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs756871251; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 43/111 reads (39%) | catalogued as rs745872748; called by mutect2, varscan2
- TENM4 | c.8303G>A p.R2768Q | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs374118156, COSV53619514; called by muse, varscan2
- TET3 | c.5243dup p.T1749Hfs*5 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs759623160; called by mutect2, varscan2
- TFEB | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs779275045, COSV57826701; called by muse, mutect2
- THBS2 | c.1903G>A p.G635S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs780999116, COSV64680008; called by muse, mutect2, varscan2
- TLE2 | c.1244del p.G415Efs*26 | Frame Shift Del (DEL) | VAF 42/97 reads (43%) | catalogued as rs1357564875, COSV53578258, COSV53581468; called by mutect2, pindel, varscan2
- TNFRSF6B | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs750495971; called by muse, mutect2, varscan2
- TNRC18 | c.3698C>T p.P1233L | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs778305819; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 47/138 reads (34%) | catalogued as rs758129598; called by mutect2, varscan2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TRAPPC12 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760250849, COSV60846641; called by muse, mutect2, varscan2
- TSPAN19 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs777078565, COSV101468087; called by muse, mutect2, varscan2
- TTLL4 | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs753204124, COSV51435180; called by muse, mutect2, varscan2
- TUBB6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs202041514; called by muse, mutect2, varscan2
- UBQLN3 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531602870, COSV61163520; called by muse, mutect2
- ULK1 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs565402146, COSV58857163; called by muse, mutect2, varscan2
- UNC13C | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs773255518, COSV52920039; called by muse, mutect2, varscan2
- USP34 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV68401388; called by muse, mutect2, varscan2
- USP6 | c.2120dup p.L707Ffs*19 | Frame Shift Ins (INS) | VAF 44/153 reads (29%) | catalogued as rs1157791748; called by mutect2, pindel, varscan2
- USP9X | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 53/166 reads (32%) | catalogued as COSV100199493; called by muse, mutect2, varscan2
- VPS51 | c.73del p.E25Rfs*13 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs1215813683, COSV99661065; called by mutect2, pindel, varscan2
- VPS72 | c.17del p.G6Afs*79 | Frame Shift Del (DEL) | VAF 58/256 reads (23%) | catalogued as rs1180303784; called by mutect2, pindel, varscan2
- VRTN | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.613); catalogued as rs1197460141, COSV56441154; called by muse, mutect2, varscan2
- VWC2 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs985676418, COSV61492165; called by muse, mutect2, varscan2
- WDR35 | c.2480G>A p.R827Q (on ENST00000345530 / NM_001006657.2; = p.R816Q on NM_020779.4) | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs539243373, COSV55601040; called by muse, mutect2, varscan2
- ZBED4 | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs150596388; called by muse, mutect2, varscan2
- ZBTB12 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1163402311, COSV64993983; called by muse, mutect2, varscan2
- ZDHHC20 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241733460, COSV100203407; called by muse, mutect2, varscan2
- ZFR2 | c.563del p.P188Rfs*239 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs764459144; called by mutect2, pindel, varscan2
- ZFYVE28 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754752842; called by muse, mutect2, varscan2
- ZNF232 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 7/143 reads (5%) | catalogued as COSV51502568; called by muse, mutect2
- ZNF462 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779730327; called by muse, mutect2, varscan2
- ZNF467 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199926663; called by muse, mutect2, varscan2
- ZNRF2 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59911012; called by muse, varscan2
- ZP2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604453, COSV54812388; called by muse, mutect2, varscan2
- ZYX | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs781348336; called by muse, mutect2, varscan2
- A4GALT | c.201del p.T68Pfs*46 | Frame Shift Del (DEL) | VAF 70/254 reads (28%) | called by mutect2, varscan2
- ACSL4 | c.1482C>G p.C494W (on ENST00000340800 / NM_022977.2; = p.C453W on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS15 | c.1439G>A p.C480Y | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 133/348 reads (38%) | called by muse, mutect2, varscan2
- ADGRG4 | c.6290A>G p.D2097G | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1B15 | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ALK | c.2722del p.Q908Rfs*3 | Frame Shift Del (DEL) | VAF 72/202 reads (36%) | called by mutect2, pindel, varscan2
- ALMS1 | c.9322G>A p.A3108T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ALPK1 | c.1363dup p.I455Nfs*3 | Frame Shift Ins (INS) | VAF 51/159 reads (32%) | called by mutect2, pindel, varscan2
- ANKFY1 | c.3380G>A p.R1127H (on ENST00000341657 / NM_001330063.2; = p.R1128H on NM_016376.5) | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD36C | c.2630dup p.D878Gfs*6 | Frame Shift Ins (INS) | VAF 58/185 reads (31%) | called by mutect2, varscan2
- ANKS1A | c.1043T>A p.I348N | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AP3B1 | c.1789del p.I597Yfs*3 | Frame Shift Del (DEL) | VAF 45/144 reads (31%) | called by mutect2, varscan2
- ARHGDIB | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGEF40 | c.3332del p.P1111Lfs*5 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.3478_3479del p.L1160Kfs*32 | Frame Shift Del (DEL) | VAF 84/257 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.5752C>T p.R1918W | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ARID1A | c.6420dup p.F2141Lfs*9 | Frame Shift Ins (INS) | VAF 53/236 reads (22%) | called by mutect2, pindel, varscan2
- ARID1B | c.228dup p.A77Rfs*155 | Frame Shift Ins (INS) | VAF 104/352 reads (30%) | called by pindel, varscan2
- ARID1B | c.831dup p.G278Rfs*257 | Frame Shift Ins (INS) | VAF 52/274 reads (19%) | called by pindel, varscan2
- ATF6 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1B1 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 132/470 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ATXN2 | c.2191C>T p.P731S (on ENST00000550104; = p.P571S on NM_002973.4) | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- AWAT1 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BRWD1 | c.6364G>A p.A2122T | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- C20orf204 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C21orf58 | c.540del p.T181Rfs*41 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- CA8 | c.240_241del p.C80* | Nonsense Mutation (DEL) | VAF 48/164 reads (29%) | called by pindel, varscan2
- CACHD1 | c.3667G>T p.G1223* | Nonsense Mutation (SNP) | VAF 21/285 reads (7%) | called by muse, mutect2
- CACNA1D | c.5998del p.L2000* (on ENST00000350061 / NM_001128840.3; = p.L2020* on NM_000720.4) | Frame Shift Del (DEL) | VAF 47/130 reads (36%) | called by mutect2, varscan2
- CACNA1H | c.6590del p.P2197Lfs*20 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- CCAR1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- CCDC134 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD46 | c.198del p.G67Dfs*40 | Frame Shift Del (DEL) | VAF 108/438 reads (25%) | called by mutect2, pindel, varscan2
- CDH5 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEBPZ | c.2460dup p.V821Sfs*4 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- CEP135 | c.3223C>G p.Q1075E | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CEP250 | c.3397_3398del p.I1133Hfs*65 | Frame Shift Del (DEL) | VAF 68/205 reads (33%) | called by pindel, varscan2
- CEP295 | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 74/215 reads (34%) | called by muse, mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 129/378 reads (34%) | called by mutect2, pindel, varscan2
- CIART | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CIT | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CLTC | c.1574G>C p.S525T | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CNGA3 | c.1116del p.V373* | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | called by mutect2, pindel, varscan2
- CNGB1 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- COBLL1 | c.2090dup p.N697Kfs*4 (on ENST00000392717; = p.N659Kfs*4 on NM_014900.5) | Frame Shift Ins (INS) | VAF 53/167 reads (32%) | called by mutect2, pindel, varscan2
- COL10A1 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- COL2A1 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2
- COL4A5 | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL8A2 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 109/242 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRISP2 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK1D | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 166/474 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTCF | c.556dup p.Q186Pfs*5 | Frame Shift Ins (INS) | VAF 132/360 reads (37%) | called by mutect2, pindel, varscan2
- CZIB | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DIMT1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 75/200 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLK2 | c.1016del p.P339Lfs*96 | Frame Shift Del (DEL) | VAF 55/153 reads (36%) | called by mutect2, pindel, varscan2
- DNAH10 | c.12139G>A p.V4047I (on ENST00000409039; = p.V3986I on NM_207437.3) | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | called by mutect2, pindel, varscan2
- DOT1L | c.1516del p.Q506Sfs*51 | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | called by mutect2, varscan2
- DSP | c.4190A>T p.N1397I | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC2H1 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DYRK2 | c.1519dup p.L507Pfs*4 (on ENST00000344096 / NM_006482.3; = p.L434Pfs*4 on NM_003583.4) | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.1539A>T p.K513N | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ELAVL1 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- FABP1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM155A | c.595del p.A199Rfs*9 | Frame Shift Del (DEL) | VAF 39/125 reads (31%) | called by mutect2, pindel, varscan2
- FAM181A | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM181B | c.1142C>A p.A381D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- FARP1 | c.1627T>G p.F543V | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FBXL22 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FBXO24 | c.230G>A p.G77D (on ENST00000241071 / NM_033506.3; = p.G115D on NM_012172.5) | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- FBXO30 | c.2028del p.E677Kfs*22 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- FLNC | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FO393400.1 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FREM2 | c.5974G>A p.E1992K | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSIP2 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FZD1 | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAGE2E | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 90/1656 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- GCDH | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GFI1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPM6A | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR26 | c.829del p.V277Cfs*33 | Frame Shift Del (DEL) | VAF 110/264 reads (42%) | called by mutect2, varscan2
- GRB10 | c.1279G>A p.V427I (on ENST00000398812; = p.V381I on NM_001001549.3) | Missense Mutation (SNP) | VAF 102/401 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GRM2 | c.543dup p.A182Cfs*7 | Frame Shift Ins (INS) | VAF 52/175 reads (30%) | called by mutect2, pindel, varscan2
- HAPLN4 | c.508del p.R170Vfs*7 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- HAS2 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- HCN4 | c.3040del p.A1014Lfs*4 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- HDAC7 | c.2304del p.M769Wfs*12 (on ENST00000427332; = p.M808Wfs*12 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 69/223 reads (31%) | called by mutect2, pindel, varscan2
- HECTD4 | c.9131G>A p.G3044D | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HFM1 | c.1513A>T p.T505S | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HOOK1 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- HTT | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- IBA57 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.243); called by muse, mutect2
- IBTK | c.939A>T p.Q313H | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGKV6D-21 | c.45A>G p.P15= | Splice Region (SNP) | VAF 76/268 reads (28%) | called by muse, mutect2, varscan2
- ITGA8 | c.3137A>G p.Q1046R | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JHY | c.587del p.L196* | Frame Shift Del (DEL) | VAF 110/372 reads (30%) | called by mutect2, pindel, varscan2
- KCNC4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- KCNN2 | c.740dup p.S248Ifs*6 (on ENST00000264773; = p.S460Ifs*6 on NM_021614.4) | Frame Shift Ins (INS) | VAF 87/264 reads (33%) | called by mutect2, pindel, varscan2
- KCP | c.1582G>A p.A528T (on ENST00000620378; = p.A585T on NM_001366122.1) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- KIDINS220 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF18B | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 137/352 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIFAP3 | c.163del p.I55Sfs*13 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- KLHL18 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- KLLN | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- KMT2B | c.1673A>C p.E558A | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KRIT1 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2
- LAP3 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LMF2 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LOXHD1 | c.5297C>T p.T1766I (on ENST00000642948; = p.T1704I on NM_144612.7) | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN3 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC75A | c.521dup p.D175Rfs*78 (on ENST00000470794 / NM_001113567.3; = p.R136Qfs*12 on NM_207387.4) | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- LSP1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LUZP1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- LYST | c.5295A>C p.Q1765H | Missense Mutation (SNP) | VAF 111/423 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LYST | c.1775T>C p.I592T | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MACF1 | c.15527T>C p.V5176A (on ENST00000372915; = p.V3109A on NM_012090.5) | Missense Mutation (SNP) | VAF 54/177 reads (31%) | called by muse, mutect2, varscan2
- MBD6 | c.1328del p.P443Qfs*44 | Frame Shift Del (DEL) | VAF 58/166 reads (35%) | called by mutect2, pindel, varscan2
- MITF | c.1318A>G p.T440A (on ENST00000448226 / NM_006722.3; = p.T340A on NM_000248.4) | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MNX1 | c.690C>T p.N230= | Splice Region (SNP) | VAF 42/147 reads (29%) | called by muse, mutect2, varscan2
- MON1B | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MORC1 | c.179del p.G60Dfs*13 | Frame Shift Del (DEL) | VAF 66/220 reads (30%) | called by mutect2, pindel, varscan2
- MRPL34 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- MST1R | c.1373A>T p.N458I | Missense Mutation (SNP) | VAF 156/479 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBPF1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by mutect2, varscan2
- NIPAL4 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR2F1 | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4X1 | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR7D2 | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOG | c.4430G>A p.G1477D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTUD4 | c.2917_2918dup p.T974Kfs*16 (on ENST00000447906 / NM_001366057.1; = p.T909Kfs*16 on NM_001102653.1) | Frame Shift Ins (INS) | VAF 62/254 reads (24%) | called by mutect2, varscan2
- PABPC4 | c.1559T>C p.V520A | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPPA2 | c.2535dup p.I846Hfs*24 | Frame Shift Ins (INS) | VAF 33/175 reads (19%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 118/395 reads (30%) | called by pindel, varscan2
- PCDHGA4 | c.2344C>T p.Q782* | Nonsense Mutation (SNP) | VAF 134/362 reads (37%) | called by muse, mutect2, varscan2
- PCNX2 | c.2369A>G p.Q790R | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.153); called by muse, varscan2
- PDE3B | c.761del p.G254Afs*35 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- PGAM5 | c.443C>A p.S148* | Nonsense Mutation (SNP) | VAF 96/307 reads (31%) | called by muse, mutect2, varscan2
- PGAP1 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PHGR1 | c.74del p.P25Lfs*83 | Frame Shift Del (DEL) | VAF 70/192 reads (36%) | called by pindel, varscan2
- PHTF2 | c.1108T>C p.Y370H (on ENST00000248550 / NM_001366089.1; = p.Y332H on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIM1 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLCL1 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNISR | c.2089dup p.R697Kfs*7 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- POLK | c.507dup p.N170Qfs*3 | Frame Shift Ins (INS) | VAF 48/322 reads (15%) | called by mutect2, pindel, varscan2
- POLK | c.2527del p.R843Gfs*4 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- POLR1F | c.932del p.K311Rfs*15 | Frame Shift Del (DEL) | VAF 46/112 reads (41%) | called by mutect2, varscan2
- PPL | c.2602A>G p.R868G | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- PRRT3 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 45/114 reads (39%) | called by mutect2, varscan2
- RAD54L2 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RANBP2 | c.6368C>T p.A2123V | Missense Mutation (SNP) | VAF 283/775 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAP1GAP2 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCOR3 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RGS12 | c.2279del p.K760Rfs*31 | Frame Shift Del (DEL) | VAF 46/129 reads (36%) | called by mutect2, pindel, varscan2
- RPAP2 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPIA | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 100/257 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RPL22 | c.267dup p.Y90Ifs*6 | Frame Shift Ins (INS) | VAF 82/270 reads (30%) | called by mutect2, pindel, varscan2
- RRP12 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTN1 | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 116/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR1 | c.13159A>G p.T4387A | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SAMD7 | c.576del p.A193Lfs*2 | Frame Shift Del (DEL) | VAF 72/241 reads (30%) | called by mutect2, pindel, varscan2
- SAMD9 | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2
- SDK2 | c.4979A>G p.K1660R | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SFXN5 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC15A3 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- SLC35F2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SLC39A10 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, varscan2
- SLC39A14 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SLC41A3 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A6 | c.130_132del p.E44del | In Frame Del (DEL) | VAF 135/394 reads (34%) | called by mutect2, pindel, varscan2
- SOD2 | c.529_530dup p.P178Ffs*25 | Frame Shift Ins (INS) | VAF 39/118 reads (33%) | called by mutect2, pindel, varscan2
- SPATA16 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPEG | c.8436dup p.T2813Hfs*17 | Frame Shift Ins (INS) | VAF 34/167 reads (20%) | called by pindel, varscan2
- SPIN4 | c.149dup p.E51Gfs*27 | Frame Shift Ins (INS) | VAF 53/171 reads (31%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.2429del p.L810Pfs*11 | Frame Shift Del (DEL) | VAF 65/218 reads (30%) | called by mutect2, pindel, varscan2
- SPTLC3 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STARD4 | c.235T>C p.W79R | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- STIM2 | c.1609del p.H537Tfs*64 | Frame Shift Del (DEL) | VAF 50/364 reads (14%) | called by mutect2, pindel, varscan2
- SUPT20H | c.1838del p.N613Ifs*8 (on ENST00000350612 / NM_001014286.3; = p.N614Ifs*8 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- SYDE1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TAF7L | c.508del p.T170Pfs*35 | Frame Shift Del (DEL) | VAF 69/190 reads (36%) | called by mutect2, pindel, varscan2
- TELO2 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TEX13C | c.1804del p.L602Wfs*9 | Frame Shift Del (DEL) | VAF 189/614 reads (31%) | called by mutect2, pindel, varscan2
- TFAP2A | c.1012A>T p.N338Y (on ENST00000482890; = p.N330Y on NM_001032280.3) | Missense Mutation (SNP) | VAF 152/395 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TFIP11 | c.829_831del p.K277del | In Frame Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- THAP4 | c.332del p.G111Vfs*2 | Frame Shift Del (DEL) | VAF 80/228 reads (35%) | called by mutect2, pindel, varscan2
- THRB | c.800A>G p.E267G | Missense Mutation (SNP) | VAF 139/411 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TLN2 | c.1292+4_1292+7del p.X431_splice | Splice Site (DEL) | VAF 56/160 reads (35%) | called by pindel, varscan2
- TM6SF1 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMCC3 | c.535dup p.H179Pfs*24 | Frame Shift Ins (INS) | VAF 38/140 reads (27%) | called by mutect2, pindel, varscan2
- TMEM151B | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TMUB2 | c.717C>G p.H239Q (on ENST00000538716 / NM_001353177.2; = p.H219Q on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFSF10 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOGARAM2 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRABD2B | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRIM66 | c.3322G>A p.V1108M | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TRIM8 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- TRRAP | c.9195T>A p.H3065Q (on ENST00000359863 / NM_001244580.1; = p.H3036Q on NM_003496.3) | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TSGA10 | c.1122del p.K374Nfs*2 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- TTC7B | c.1745A>T p.N582I | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE2D4 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- UNC5A | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- USP28 | c.1706C>G p.T569S | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP5 | c.2314A>G p.M772V (on ENST00000229268 / NM_001098536.2; = p.M749V on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- UTP11 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- VWDE | c.279_280del p.L95Efs*67 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | called by mutect2, pindel, varscan2
- WDFY4 | c.1205G>A p.C402Y | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDHD1 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, varscan2
- WDR87 | c.4127del p.L1376* | Frame Shift Del (DEL) | VAF 50/133 reads (38%) | called by mutect2, pindel, varscan2
- WNT8A | c.792C>G p.S264R | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZBTB1 | c.1571del p.K524Sfs*25 | Frame Shift Del (DEL) | VAF 47/152 reads (31%) | called by mutect2, pindel, varscan2
- ZEB2 | c.2094C>G p.Y698* | Nonsense Mutation (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- ZNF180 | c.1324T>C p.C442R | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF337 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 104/274 reads (38%) | called by muse, mutect2, varscan2
- ZNF503 | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ZNF547 | c.-12-5T>C | Splice Region (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- ZNF561 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF793 | c.247T>C p.W83R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF841 | c.1223G>A p.W408* (on ENST00000426391 / NM_001369830.1; = p.W524* on NM_001136499.1 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- ABCA3 | c.96A>G p.P32= | Silent (SNP) | VAF 165/434 reads (38%) | catalogued as rs1038868525; called by muse, mutect2, varscan2
- ABCA5 | c.3852T>C p.C1284= | Silent (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- ABHD12 | c.453C>T p.N151= | Silent (SNP) | VAF 112/330 reads (34%) | catalogued as rs375299452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSL1 | c.966C>T p.L322= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as rs1244158742; called by muse, mutect2, varscan2
- ACTR10 | c.900A>G p.A300= | Silent (SNP) | VAF 77/159 reads (48%) | called by muse, mutect2, varscan2
- ADCY2 | c.1797G>A p.A599= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as rs778398128, COSV57859762; called by muse, mutect2, varscan2
- AGO1 | c.1782A>G p.A594= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as rs1557621093; called by muse, mutect2, varscan2
- APBB1IP | c.1992C>T p.N664= | Silent (SNP) | VAF 223/561 reads (40%) | catalogued as COSV66133844; called by muse, mutect2, varscan2
- ARHGAP30 | c.1812T>C p.N604= | Silent (SNP) | VAF 64/340 reads (19%) | catalogued as rs139339322; called by muse, mutect2, varscan2
- ARHGEF12 | c.3819C>T p.S1273= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as rs370971203; called by muse, mutect2, varscan2
- ATP10B | c.1044C>T p.F348= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs541851085, COSV58781352; called by muse, mutect2, varscan2
- ATP8A1 | c.1833G>T p.V611= | Silent (SNP) | VAF 105/300 reads (35%) | called by muse, mutect2, varscan2
- ATP8B2 | c.2697G>A p.L899= (on ENST00000672630; = p.L866= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 101/464 reads (22%) | called by muse, mutect2, varscan2
- B9D1 | c.315C>T p.A105= | Silent (SNP) | VAF 160/390 reads (41%) | catalogued as rs776662206, COSV52069531; ClinVar: likely benign; called by muse, mutect2, varscan2
- BARHL2 | c.243G>A p.A81= | Silent (SNP) | VAF 95/301 reads (32%) | called by muse, mutect2, varscan2
- BBS7 | c.192G>A p.P64= | Silent (SNP) | VAF 78/231 reads (34%) | catalogued as rs775906320; ClinVar: likely benign; called by muse, varscan2
- BCOR | c.1008G>A p.S336= | Silent (SNP) | VAF 77/204 reads (38%) | catalogued as rs759420433, COSV60723054; called by muse, mutect2, varscan2
- BTBD17 | c.1410C>T p.Y470= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- C9orf24 | c.204A>G p.V68= | Silent (SNP) | VAF 53/161 reads (33%) | called by muse, mutect2, varscan2
- CALHM3 | c.73C>T p.L25= | Silent (SNP) | VAF 50/141 reads (35%) | called by muse, mutect2, varscan2
- CAPN13 | c.327G>A p.R109= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1295742702; called by muse, mutect2, varscan2
- CCDC142 | c.195G>A p.E65= | Silent (SNP) | VAF 31/78 reads (40%) | called by muse, varscan2
- CDR1 | c.480C>T p.S160= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as rs146276960, COSV100983394, COSV65164211; called by muse, mutect2, varscan2
- CEP104 | c.483C>T p.S161= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- CHMP5 | c.633T>C p.F211= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as rs766894190; called by muse, mutect2, varscan2
- CLDN14 | c.315G>A p.T105= | Silent (SNP) | VAF 93/256 reads (36%) | catalogued as rs781167430; called by muse, mutect2, varscan2
- COL1A2 | c.3682C>T p.L1228= | Silent (SNP) | VAF 53/303 reads (17%) | catalogued as rs1445979704; called by muse, mutect2, varscan2
- CRACD | c.849G>A p.A283= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs576383014; called by muse, mutect2, varscan2
- CRYBG3 | c.1041C>T p.S347= | Silent (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- CSPG5 | c.1557C>T p.P519= (on ENST00000383738 / NM_001206943.2; = p.P492= on NM_006574.4) | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, varscan2
- CYP4F11 | c.1137C>T p.P379= | Silent (SNP) | VAF 66/171 reads (39%) | called by muse, mutect2, varscan2
- DBN1 | c.15C>T p.S5= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs1260319448; called by muse, mutect2, varscan2
- DCLK1 | c.990G>A p.S330= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs200783749, COSV55171920; called by muse, mutect2, varscan2
- DHRSX | c.660C>T p.Y220= | Silent (SNP) | VAF 124/357 reads (35%) | called by muse, mutect2, varscan2
- DNAH1 | c.4473G>A p.A1491= | Silent (SNP) | VAF 78/269 reads (29%) | catalogued as rs1015046493; called by muse, mutect2, varscan2
- DNAH17 | c.3319A>C p.R1107= | Silent (SNP) | VAF 92/210 reads (44%) | catalogued as COSV101102767; called by muse, mutect2, varscan2
- DOCK3 | c.6075C>T p.H2025= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs782779611; called by muse, mutect2, varscan2
- DSCAML1 | c.5592C>A p.A1864= (on ENST00000321322; = p.A1804= on NM_020693.4) | Silent (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- DSG3 | c.1644G>A p.S548= | Silent (SNP) | VAF 59/164 reads (36%) | catalogued as rs373234061; called by muse, mutect2, varscan2
- EMX2 | c.516C>A p.A172= | Silent (SNP) | VAF 46/158 reads (29%) | called by mutect2, varscan2
- ERRFI1 | c.33C>A p.I11= | Silent (SNP) | VAF 55/149 reads (37%) | called by muse, mutect2, varscan2
- EXOC3 | c.1983T>C p.A661= | Silent (SNP) | VAF 67/197 reads (34%) | called by muse, mutect2, varscan2
- FGD1 | c.1983A>G p.S661= | Silent (SNP) | VAF 20/605 reads (3%) | called by muse, mutect2
- FNBP1L | c.1452C>T p.D484= (on ENST00000271234 / NM_001164473.2; = p.D426= on NM_017737.5) | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as rs1271367450; called by muse, mutect2, varscan2
- FOXM1 | c.1470G>A p.P490= | Silent (SNP) | VAF 79/191 reads (41%) | catalogued as rs371830965; called by muse, mutect2, varscan2
- FZD5 | c.1275G>A p.S425= | Silent (SNP) | VAF 71/223 reads (32%) | called by muse, mutect2, varscan2
- GBA | c.987C>T p.H329= | Silent (SNP) | VAF 99/361 reads (27%) | called by muse, mutect2, varscan2
- GLYCTK | c.969C>T p.A323= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as rs764235047; called by muse, mutect2, varscan2
- GPR158 | c.3351C>T p.S1117= | Silent (SNP) | VAF 76/211 reads (36%) | catalogued as rs544868296, COSV100893326; called by muse, mutect2, varscan2
- GRIN3B | c.3012C>T p.R1004= | Silent (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2
- GZF1 | c.1020C>T p.H340= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs546426650; called by muse, mutect2, varscan2
- HKDC1 | c.2478C>T p.S826= | Silent (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- HLA-DRB1 | c.150G>A p.T50= | Silent (SNP) | VAF 103/377 reads (27%) | called by muse, varscan2
- HMCN2 | c.4341G>A p.V1447= | Silent (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- HTT | c.207G>A p.P69= | Silent (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- IFNA1 | c.330C>T p.T110= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs774504120; called by muse, mutect2, varscan2
- IFNL1 | c.555C>T p.A185= | Silent (SNP) | VAF 78/190 reads (41%) | catalogued as rs780322106, COSV61317636; called by mutect2, varscan2
- IPO4 | c.1830G>A p.T610= | Silent (SNP) | VAF 84/202 reads (42%) | catalogued as rs774859666; called by muse, mutect2, varscan2
- ITGA11 | c.597C>T p.I199= | Silent (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- KCNG3 | c.1149A>C p.T383= | Silent (SNP) | VAF 74/190 reads (39%) | called by muse, mutect2, varscan2
- KIF3C | c.924G>A p.A308= | Silent (SNP) | VAF 134/370 reads (36%) | catalogued as rs375524604; called by muse, mutect2, varscan2
- LAMC2 | c.2412A>T p.G804= | Silent (SNP) | VAF 126/470 reads (27%) | called by muse, varscan2
- LCP2 | c.528G>C p.R176= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- LDOC1 | c.414C>T p.D138= | Silent (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- LGALSL | c.219T>C p.C73= | Silent (SNP) | VAF 71/201 reads (35%) | catalogued as rs200873971; called by muse, mutect2, varscan2
- LRRC4C | c.1659G>A p.Q553= | Silent (SNP) | VAF 77/209 reads (37%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.2145C>T p.C715= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV101280569; called by muse, mutect2, varscan2
- MACF1 | c.10854C>A p.T3618= (on ENST00000372915; = p.T1551= on NM_012090.5) | Silent (SNP) | VAF 44/120 reads (37%) | called by muse, mutect2, varscan2
- MAST4 | c.4281C>T p.I1427= (on ENST00000403625 / NM_001164664.2; = p.I1238= on NM_015183.3) | Silent (SNP) | VAF 75/213 reads (35%) | called by muse, mutect2, varscan2
- MBNL2 | c.606C>T p.P202= | Silent (SNP) | VAF 84/226 reads (37%) | catalogued as rs373489782; called by muse, mutect2, varscan2
- MFAP3 | c.258C>T p.H86= | Silent (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- MMP17 | c.393C>T p.T131= | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- MRPL19 | c.78C>T p.L26= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs1288933444, COSV62567684; called by muse, mutect2, varscan2
- MS4A4E | c.975C>T p.S325= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs941124899; called by muse, mutect2, varscan2
- MUC2 | c.969G>A p.E323= | Silent (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- MYH9 | c.2154G>A p.R718= | Silent (SNP) | VAF 188/495 reads (38%) | called by muse, mutect2, varscan2
- MYO16 | c.4410G>A p.G1470= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- MYO5A | c.2397C>T p.Y799= | Silent (SNP) | VAF 98/306 reads (32%) | catalogued as rs772277161, COSV62562782; called by mutect2, varscan2
- MYORG | c.427C>T p.L143= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- NINL | c.2262C>T p.R754= | Silent (SNP) | VAF 43/139 reads (31%) | called by muse, mutect2, varscan2
- NOL4 | c.1164C>T p.H388= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as rs554528321, COSV52343721; called by muse, mutect2, varscan2
- NT5DC3 | c.348G>A p.T116= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as rs771532802; called by muse, mutect2, varscan2
- NUMA1 | c.4812G>A p.E1604= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs765091867; called by muse, mutect2, varscan2
- NUP155 | c.1053T>C p.S351= (on ENST00000231498 / NM_153485.3; = p.S292= on NM_004298.4) | Silent (SNP) | VAF 91/240 reads (38%) | called by muse, mutect2, varscan2
- OBSCN | c.18066C>T p.D6022= | Silent (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- OPLAH | c.3549G>A p.E1183= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as COSV66298206; called by muse, mutect2
- OR7A10 | c.198G>A p.L66= | Silent (SNP) | VAF 63/171 reads (37%) | catalogued as COSV99932382; called by muse, mutect2, varscan2
- OR8B12 | c.390G>A p.L130= | Silent (SNP) | VAF 40/108 reads (37%) | called by muse, mutect2, varscan2
- PASK | c.2517C>T p.S839= | Silent (SNP) | VAF 94/262 reads (36%) | catalogued as rs778801015; called by muse, mutect2, varscan2
- PCDHGA7 | c.810C>T p.D270= | Silent (SNP) | VAF 72/176 reads (41%) | catalogued as COSV53912854, COSV53988586; called by muse, varscan2
- PHLDB3 | c.657G>A p.V219= | Silent (SNP) | VAF 94/238 reads (39%) | called by muse, mutect2, varscan2
- PITPNM2 | c.3924C>T p.H1308= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs367690986; called by muse, mutect2, varscan2
- PIWIL1 | c.1782G>A p.Q594= | Silent (SNP) | VAF 145/403 reads (36%) | catalogued as rs1446904021, COSV55347463; called by muse, mutect2, varscan2
- PLEKHG2 | c.789C>T p.R263= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs759041640; called by muse, mutect2, varscan2
- POLR1A | c.1839C>T p.C613= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs559154673; called by muse, mutect2, varscan2
- POM121C | c.174G>A p.L58= | Silent (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- PRRC2A | c.711T>A p.P237= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- RBMXL3 | c.2169C>T p.R723= | Silent (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- RGS5 | c.18A>G p.A6= | Silent (SNP) | VAF 14/221 reads (6%) | called by muse, mutect2
- RSBN1L | c.249C>T p.P83= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV58509214; called by muse, mutect2, varscan2
- RYR1 | c.4083G>A p.P1361= | Silent (SNP) | VAF 64/140 reads (46%) | catalogued as rs764202932; ClinVar: likely benign; called by muse, mutect2, varscan2
- SALL3 | c.1129C>T p.L377= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs1248859182; called by muse, varscan2
- SH2B3 | c.63G>A p.A21= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as rs772256437; called by muse, mutect2, varscan2
- SLC45A1 | c.1086C>T p.S362= | Silent (SNP) | VAF 129/291 reads (44%) | catalogued as rs761492222; called by muse, mutect2, varscan2
- SNRNP70 | c.237G>A p.Q79= | Silent (SNP) | VAF 58/156 reads (37%) | called by muse, mutect2, varscan2
- SOX30 | c.594C>T p.G198= | Silent (SNP) | VAF 160/399 reads (40%) | catalogued as COSV53937931; called by muse, mutect2, varscan2
- SPTB | c.5523C>T p.F1841= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as rs772509663, COSV67633464; called by muse, mutect2, varscan2
- STRA6 | c.1009C>T p.L337= | Silent (SNP) | VAF 153/457 reads (33%) | catalogued as rs558046841; called by muse, mutect2, varscan2
- STX11 | c.669C>T p.D223= | Silent (SNP) | VAF 99/286 reads (35%) | catalogued as COSV62448558; called by muse, mutect2, varscan2
- SUPT20HL2 | c.2295G>A p.Q765= | Silent (SNP) | VAF 9/214 reads (4%) | called by muse, mutect2
- TADA2A | c.1101C>G p.L367= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as rs752587220; called by muse, varscan2
- TAF4 | c.1467G>A p.A489= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs751093736, COSV53335661; called by muse, mutect2, varscan2
- TCHH | c.5590C>T p.L1864= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as COSV64277606; called by muse, mutect2, varscan2
- TECPR1 | c.1017C>T p.N339= | Silent (SNP) | VAF 107/286 reads (37%) | catalogued as rs769134413, COSV101130616; called by muse, mutect2, varscan2
- TELO2 | c.1899C>A p.P633= | Silent (SNP) | VAF 75/181 reads (41%) | called by muse, mutect2, varscan2
- TERT | c.672C>T p.R224= | Silent (SNP) | VAF 110/271 reads (41%) | catalogued as rs996032219; called by muse, mutect2, varscan2
- TIAM1 | c.606C>T p.S202= | Silent (SNP) | VAF 103/292 reads (35%) | catalogued as rs1304656057, COSV54578238; called by muse, mutect2, varscan2
- TMED9 | c.22C>T p.L8= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as COSV60263719; called by muse, mutect2, varscan2
- TNKS | c.2049G>A p.R683= | Silent (SNP) | VAF 65/189 reads (34%) | called by muse, mutect2, varscan2
- TPTE | c.624G>A p.L208= (on ENST00000618007 / NM_199261.4; = p.L190= on NM_199259.4) | Silent (SNP) | VAF 27/223 reads (12%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1995G>A p.T665= | Silent (SNP) | VAF 195/528 reads (37%) | catalogued as rs375784438; called by muse, mutect2, varscan2
- TRIP10 | c.1164C>T p.T388= (on ENST00000313244 / NM_001288962.2; = p.T332= on NM_004240.4) | Silent (SNP) | VAF 100/270 reads (37%) | catalogued as rs371917765; called by muse, mutect2, varscan2
- TRPM4 | c.258G>A p.K86= | Silent (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- TRPM4 | c.786G>A p.T262= | Silent (SNP) | VAF 38/293 reads (13%) | catalogued as rs759568404; called by muse, mutect2, varscan2
- TSPYL6 | c.153G>A p.P51= | Silent (SNP) | VAF 78/235 reads (33%) | catalogued as rs761886975, COSV100336729; called by muse, mutect2, varscan2
- TTC26 | c.1509C>A p.A503= | Silent (SNP) | VAF 49/169 reads (29%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.1353G>A p.P451= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs575155995, COSV50552755, COSV99955570; ClinVar: likely benign; called by muse, mutect2, varscan2
- UFD1 | c.600C>T p.P200= | Silent (SNP) | VAF 87/262 reads (33%) | catalogued as rs770915077; called by muse, mutect2, varscan2
- USP20 | c.921C>T p.A307= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs751415528, COSV59614909; called by muse, mutect2, varscan2
- USP25 | c.198G>A p.E66= | Silent (SNP) | VAF 65/183 reads (36%) | called by muse, mutect2, varscan2
- UTRN | c.9735G>A p.P3245= | Silent (SNP) | VAF 68/220 reads (31%) | catalogued as rs375428730; called by muse, mutect2, varscan2
- VSTM2B | c.408C>T p.D136= | Silent (SNP) | VAF 206/469 reads (44%) | called by muse, mutect2, varscan2
- WDR43 | c.1929C>A p.A643= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV68018558; called by muse, mutect2, varscan2
- WDR91 | c.1692T>C p.A564= | Silent (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.21C>T p.R7= | Silent (SNP) | VAF 50/120 reads (42%) | called by muse, mutect2, varscan2
- ZEB2 | c.3432C>T p.G1144= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs768007761, COSV57957231; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZEB2 | c.1533C>T p.V511= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as rs587780994, COSV57964693; ClinVar: benign; called by muse, mutect2, varscan2
- ZIC3 | c.789G>A p.R263= | Silent (SNP) | VAF 80/242 reads (33%) | catalogued as COSV54976565; called by muse, mutect2, varscan2
- ZMYM2 | c.2856A>G p.T952= | Silent (SNP) | VAF 63/154 reads (41%) | catalogued as rs199677304; called by muse, mutect2, varscan2
- ZMYM3 | c.1531C>T p.L511= | Silent (SNP) | VAF 57/201 reads (28%) | called by muse, mutect2, varscan2
- ZNF428 | c.267G>T p.P89= | Silent (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- ZNF44 | c.1500A>G p.K500= (on ENST00000356109 / NM_001164276.2; = p.K452= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- ABCB4 | c.*26del | 3'UTR (DEL) | VAF 63/206 reads (31%) | called by mutect2, pindel, varscan2
- AC022748.1 | n.199G>A | RNA (SNP) | VAF 22/111 reads (20%) | catalogued as rs1289979205; called by muse, mutect2, varscan2
- ACD | c.672-27del | Intron (DEL) | VAF 45/130 reads (35%) | called by mutect2, pindel, varscan2
- ADAR | c.2496+35_2496+37del | Intron (DEL) | VAF 45/130 reads (35%) | catalogued as rs779843196; called by mutect2, pindel, varscan2
- ALG2 | c.*696C>T | 3'UTR (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- AP1B1 | c.2766+42del | Intron (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP20 | c.*2227C>T | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916483 C>T | 5'Flank (SNP) | VAF 70/160 reads (44%) | catalogued as rs1350585900; called by muse, mutect2, varscan2
- AURKAIP1 | c.52+52C>T | Intron (SNP) | VAF 7/146 reads (5%) | catalogued as rs1446341121, COSV100408715; called by muse, mutect2
- C19orf12 | chr19:29715261 T>C | 5'Flank (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- C4orf50 | c.-2C>A | 5'UTR (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100135532; called by muse, mutect2
- CACYBP | c.-63C>T | 5'UTR (SNP) | VAF 109/416 reads (26%) | called by muse, mutect2, varscan2
- CARD9 | c.1434+22dup | Intron (INS) | VAF 29/89 reads (33%) | called by mutect2, pindel, varscan2
- CCM2 | c.*75C>A | 3'UTR (SNP) | VAF 77/208 reads (37%) | called by muse, mutect2, varscan2
- CEP290 | c.3573+42del | Intron (DEL) | VAF 48/173 reads (28%) | called by mutect2, pindel, varscan2
- COG1 | c.2511-34del | Intron (DEL) | VAF 47/133 reads (35%) | called by mutect2, varscan2
- CRTAP | c.*28T>C | 3'UTR (SNP) | VAF 51/131 reads (39%) | called by muse, mutect2, varscan2
- DDX49 | c.448-47C>T | Intron (SNP) | VAF 67/137 reads (49%) | catalogued as rs375606654; called by muse, mutect2, varscan2
- DEFB104A | c.-14G>A | 5'UTR (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- DHX38 | c.*310C>T | 3'UTR (SNP) | VAF 52/140 reads (37%) | called by muse, mutect2, varscan2
- DPM2 | c.3+42del | Intron (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- ENAM | c.535-51C>T | Intron (SNP) | VAF 78/198 reads (39%) | catalogued as COSV68537180; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445998 ins C | 3'Flank (INS) | VAF 69/248 reads (28%) | catalogued as rs752576998; called by mutect2, pindel, varscan2
- FBXO3 | c.1239+467G>A | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs773432042; called by muse, mutect2, varscan2
- FGD1 | c.*27del | 3'UTR (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- FMO6P | n.1182C>T | RNA (SNP) | VAF 11/265 reads (4%) | called by muse, mutect2
- GDI1 | c.992-51C>T | Intron (SNP) | VAF 40/122 reads (33%) | catalogued as rs1557199008; called by muse, mutect2, varscan2
- GPD1 | c.360+234C>T | Intron (SNP) | VAF 28/59 reads (47%) | catalogued as rs753540288; called by muse, mutect2, varscan2
- GPS2 | c.94+55A>G | Intron (SNP) | VAF 83/209 reads (40%) | called by muse, mutect2, varscan2
- GPSM2 | c.*22del | 3'UTR (DEL) | VAF 27/83 reads (33%) | catalogued as rs768946326; called by mutect2, varscan2
- H3-2 | c.*147C>T | 3'UTR (SNP) | VAF 140/668 reads (21%) | catalogued as rs370757935; called by muse, mutect2, varscan2
- HBA1 | c.301-28G>T | Intron (SNP) | VAF 18/496 reads (4%) | called by muse, mutect2
- HEPH | c.167+437T>C | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-9del | Intron (DEL) | VAF 26/88 reads (30%) | catalogued as rs57800062, COSV61159208; called by mutect2, varscan2
- HOOK2 | c.1605+31del | Intron (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- HSF4 | c.1324+34_1324+35del | Intron (DEL) | VAF 99/366 reads (27%) | called by mutect2, pindel, varscan2
- IGFN1 | c.1242-568C>T | Intron (SNP) | VAF 71/298 reads (24%) | catalogued as rs774361260, COSV55172686; called by muse, mutect2, varscan2
- IGKV1D-17 | c.-16C>A | 5'UTR (SNP) | VAF 65/152 reads (43%) | catalogued as rs565698272; called by muse, mutect2, varscan2
- ISCA1P1 | n.297G>T | RNA (SNP) | VAF 50/158 reads (32%) | called by muse, mutect2, varscan2
- ITIH5 | c.*3239dup | 3'UTR (INS) | VAF 28/62 reads (45%) | catalogued as rs1234306890; called by mutect2, varscan2
- KDM4B | c.1115+690G>A | Intron (SNP) | VAF 48/143 reads (34%) | catalogued as rs765364867; called by muse, mutect2, varscan2
- KLF6 | c.676+43G>A | Intron (SNP) | VAF 37/104 reads (36%) | catalogued as rs781390785; called by muse, mutect2, varscan2
- LDLRAD2 | c.*2038del | 3'UTR (DEL) | VAF 166/548 reads (30%) | called by mutect2, varscan2
- LGALS8 | c.-104+319del | Intron (DEL) | VAF 86/371 reads (23%) | called by mutect2, pindel, varscan2
- LITAF | c.*825del | 3'UTR (DEL) | VAF 35/98 reads (36%) | catalogued as rs199813387; called by mutect2, varscan2
- MIR548A2 | n.14A>G | RNA (SNP) | VAF 98/245 reads (40%) | called by muse, mutect2, varscan2
- MKRN1 | c.186-2427del | Intron (DEL) | VAF 26/52 reads (50%) | catalogued as rs771760476; called by mutect2, varscan2
- MLIP | c.64-9908G>A | Intron (SNP) | VAF 80/246 reads (33%) | catalogued as rs550957008; called by muse, mutect2, varscan2
- MORN1 | c.538-4580G>A | Intron (SNP) | VAF 7/158 reads (4%) | catalogued as rs956221376; called by muse, mutect2
- MTRF1L | c.806-35del | Intron (DEL) | VAF 42/122 reads (34%) | called by mutect2, pindel
- NAGPA | c.921-34del | Intron (DEL) | VAF 15/125 reads (12%) | called by mutect2, pindel, varscan2
- NDUFB10 | chr16:1965321 del C | 3'Flank (DEL) | VAF 40/122 reads (33%) | catalogued as rs747554929; called by mutect2, pindel, varscan2
- NRG3 | c.823+1847dup | Intron (INS) | VAF 49/222 reads (22%) | called by pindel, varscan2
- ODF2 | chr9:128455256 G>A | 5'Flank (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-511C>T | Intron (SNP) | VAF 124/330 reads (38%) | called by muse, mutect2, varscan2
- PIM3 | c.-19G>A | 5'UTR (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- PKIG | chr20:44623998 C>T | 3'Flank (SNP) | VAF 16/41 reads (39%) | catalogued as rs548620084; called by muse, mutect2, varscan2
- PLRG1 | c.*24C>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | catalogued as COSV57422591, COSV57424158; called by mutect2, varscan2
- PLXNC1 | c.3598-1410del | Intron (DEL) | VAF 43/174 reads (25%) | catalogued as rs777255489; called by mutect2, pindel, varscan2
- PON1 | c.781-37T>G | Intron (SNP) | VAF 57/151 reads (38%) | called by muse, mutect2, varscan2
- PPP1R18 | c.*51C>A | 3'UTR (SNP) | VAF 103/269 reads (38%) | called by muse, mutect2, varscan2
- PPP5D1 | n.491C>T | RNA (SNP) | VAF 57/229 reads (25%) | called by muse, mutect2, varscan2
- PSAP | c.*1039A>G | 3'UTR (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- PTPRO | c.-41C>A | 5'UTR (SNP) | VAF 168/471 reads (36%) | catalogued as rs375272425, COSV99841231; called by muse, mutect2, varscan2
- RAB18 | c.*956del | 3'UTR (DEL) | VAF 7/36 reads (19%) | catalogued as rs909736212; called by mutect2, varscan2
- RBM28 | c.119-1406G>A | Intron (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- RENBP | c.138-10C>G | Intron (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1524A>G | RNA (SNP) | VAF 76/2870 reads (3%) | called by muse, mutect2
- RNASEH2B | c.322-4dup | Intron (INS) | VAF 112/389 reads (29%) | catalogued as rs770781962; called by pindel, varscan2
- RNF217-AS1 | n.4139T>C | RNA (SNP) | VAF 30/70 reads (43%) | catalogued as rs1478594693; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3181del | RNA (DEL) | VAF 13/41 reads (32%) | catalogued as rs779299943; called by mutect2, pindel, varscan2
- RPS6KA1 | c.*238del | 3'UTR (DEL) | VAF 46/160 reads (29%) | catalogued as rs751407416; called by mutect2, varscan2
- SCGN | c.*2C>G | 3'UTR (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100618824; called by muse, mutect2, varscan2
- SHTN1 | c.1359+217G>A | Intron (SNP) | VAF 59/154 reads (38%) | called by muse, mutect2, varscan2
- SLF2 | c.140+41del | Intron (DEL) | VAF 12/49 reads (24%) | catalogued as rs1335900937; called by mutect2, pindel
- SNORD114-25 | n.50G>A | RNA (SNP) | VAF 17/82 reads (21%) | catalogued as rs762253283; called by muse, mutect2, varscan2
- SORCS2 | c.*8C>A | 3'UTR (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- SRSF10 | c.-6G>A | 5'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- STIMATE | chr3:52836592 A>G | 3'Flank (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- SUMF2 | c.733+264del | Intron (DEL) | VAF 16/54 reads (30%) | catalogued as COSV99305088; called by mutect2, pindel, varscan2
- TCOF1 | c.-28G>T | 5'UTR (SNP) | VAF 56/165 reads (34%) | called by muse, mutect2
- TMPRSS11F | c.1015+1865A>G | Intron (SNP) | VAF 51/141 reads (36%) | called by muse, mutect2, varscan2
- TREX2 | c.-183+471C>T | Intron (SNP) | VAF 132/379 reads (35%) | catalogued as rs782673162; called by muse, mutect2, varscan2
- TRIO | c.7632+37del | Intron (DEL) | VAF 17/45 reads (38%) | catalogued as rs1561550439; called by mutect2, pindel, varscan2
- TTBK1 | c.1986+6375C>A | Intron (SNP) | VAF 107/281 reads (38%) | catalogued as rs1301315720; called by muse, mutect2, varscan2
- TTC38 | c.616-1364G>A | Intron (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- UBE2N | c.278-36del | Intron (DEL) | VAF 46/376 reads (12%) | called by pindel, varscan2
- UBTFL2 | n.475G>A | RNA (SNP) | VAF 202/502 reads (40%) | catalogued as rs760758613; called by muse, mutect2, varscan2
- VRK3 | chr19:49972061 G>A | 3'Flank (SNP) | VAF 44/127 reads (35%) | catalogued as rs551474306; called by muse, mutect2, varscan2
- ZNF138 | c.-13del | 5'UTR (DEL) | VAF 71/237 reads (30%) | catalogued as rs1562879369; called by mutect2, pindel, varscan2
- ZNF497 | c.-111-829del | Intron (DEL) | VAF 32/109 reads (29%) | called by mutect2, pindel, varscan2
- ZNF821 | c.-78+50del | Intron (DEL) | VAF 59/194 reads (30%) | catalogued as rs762119779; called by mutect2, varscan2
